TCGA case TCGA-02-0038 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fcce7f31-a392-4177-8dca-cfbe6e73fc2e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Dead; Days to death: 326 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 48.6 years (17,749 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 29 days; Days to treatment end: 74 days; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Erlotinib Hydrochloride; Treatment intent type: Adjuvant; Days to treatment start: 113 days; Days to treatment end: 174 days; Number of cycles: 2; Treatment dose: 150 mg/day; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 49.2 years (17,988 days); Days to diagnosis: 239 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 239 (post initial treatment): Progression or recurrence: Yes; Days to progression: 239 days.
- Days to follow up: 326 days; Disease response: With Tumor.
- Karnofsky performance status: 80.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-02-0038-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-02-0038-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
  Slide TCGA-02-0038-01A-01-TS2: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-02-0038-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-02-0038-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment: Pharmaceutical therapy drug name: Tanceva.
- Drug treatment, Route of administrations: Route of administration: PO.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 326 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 326 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 239 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-02-0038-01): tumor purity 0.78, ploidy 2, whole-genome doublings 0 (call status: legacy_call).
